Somatic mutation profile of tumor specimen TCGA-NC-A5HO-01A (aliquot TCGA-NC-A5HO-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HO, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.3 years (25,694 days).
Specimen TCGA-NC-A5HO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f604989-5d49-4485-adbb-3b852728edf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HO-10A (Blood Derived Normal), aliquot TCGA-NC-A5HO-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6904dc6-20b1-4448-8629-45d13afe27d2

The open-access MAF lists 274 somatic variants for this specimen: 217 protein-altering or splice-affecting, 49 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 49, Nonsense Mutation 21, Frame Shift Del 9, Splice Site 6, Intron 4, RNA 4, In Frame Del 1, Splice Region 1, In Frame Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 6/12 reads (50%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, mutect2, varscan2
- TP53 | c.326T>G p.F109C | Missense Mutation (SNP) | VAF 30/63 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064796722, COSV52725602, COSV52838438; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO6 | c.820A>G p.I274V | Missense Mutation (SNP) | VAF 71/134 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as rs1327332306, COSV100484624; called by muse, mutect2, varscan2
- ABCB11 | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99791379; called by muse, mutect2, varscan2
- ABCB4 | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99709573; called by muse, mutect2, varscan2
- ADAMTS20 | c.3853T>A p.L1285M | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.6); catalogued as COSV101166033; called by muse, mutect2, varscan2
- ADAMTS5 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53184568, COSV99536928; called by muse, mutect2, varscan2
- ADGRB2 | c.4381-2A>T p.X1461_splice | Splice Site (SNP) | VAF 36/70 reads (51%) | catalogued as COSV99925571; called by muse, mutect2, varscan2
- ADGRG4 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs898147415, COSV99794165; called by muse, mutect2, varscan2
- ADGRL3 | c.2816C>A p.A939E (on ENST00000506720 / NM_001322402.2; = p.A871E on NM_015236.6) | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as rs777017067, COSV101546801, COSV72230433; called by muse, mutect2, varscan2
- AGO4 | c.2276A>T p.Q759L | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100942742; called by muse, mutect2
- ALMS1 | c.11412A>T p.R3804S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100040912; called by muse, mutect2, varscan2
- ALPK2 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100864026; called by muse, mutect2, varscan2
- AMER3 | c.1738G>T p.G580* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100365903, COSV58468421; called by muse, mutect2, varscan2
- AMN1 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV99861392; called by muse, mutect2, varscan2
- AP1M2 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV99140718; called by muse, mutect2, varscan2
- ARPP21 | c.1092C>A p.S364R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51812360; called by muse, mutect2, varscan2
- ASXL3 | c.1535T>C p.L512S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV99322992; called by muse, mutect2, varscan2
- ATP7A | c.3500C>A p.A1167D | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.223); catalogued as COSV100430143; called by muse, mutect2, varscan2
- BDP1 | c.4493C>A p.S1498* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100702669; called by muse, varscan2
- BIRC6 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV101427756; called by muse, mutect2, varscan2
- C10orf53 | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100934829; called by muse, mutect2, varscan2
- C1QL2 | c.822C>G p.N274K | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99732999; called by muse, mutect2, varscan2
- C6orf118 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100023966; called by muse, mutect2, varscan2
- CCDC105 | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.165); catalogued as COSV99479696; called by muse, mutect2, varscan2
- CD247 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as rs753889129, COSV100758239, COSV62980213; called by muse, mutect2, varscan2
- CDC42BPB | c.2346G>C p.K782N | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as COSV100775103; called by muse, mutect2, varscan2
- CEACAM8 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV99747375, COSV99747595; called by muse, mutect2, varscan2
- CENPE | c.3058G>C p.D1020H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV99476802; called by muse, mutect2, varscan2
- CERCAM | c.1754A>C p.H585P | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100863799; called by muse, mutect2, varscan2
- CERS1 | c.1051T>C p.*351Rext*116 | Nonstop Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99438656; called by muse, mutect2, varscan2
- CFAP44 | c.1310A>C p.N437T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.203); catalogued as COSV99868728; called by muse, mutect2, varscan2
- CFAP54 | c.5152A>G p.K1718E | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.324); catalogued as COSV100732880; called by muse, mutect2, varscan2
- CFAP65 | c.4769G>A p.W1590* | Nonsense Mutation (SNP) | VAF 32/72 reads (44%) | catalogued as rs778332734, COSV100444490; called by muse, mutect2, varscan2
- CFH | c.3174T>A p.Y1058* | Nonsense Mutation (SNP) | VAF 48/239 reads (20%) | catalogued as COSV100808626; called by muse, mutect2, varscan2
- CHSY3 | c.2026G>C p.G676R | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100518313; called by muse, mutect2, varscan2
- CLEC5A | c.254T>C p.L85S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs782124500, COSV101407740; called by muse, mutect2, varscan2
- CMYA5 | c.11962A>T p.R3988* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV101405632; called by muse, mutect2, varscan2
- CNTN6 | c.1105G>T p.G369W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100609918; called by muse, mutect2, varscan2
- COL11A1 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100614706; called by muse, mutect2, varscan2
- CRELD1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs958797144, COSV55972102, COSV55973475; called by muse, mutect2, varscan2
- CSMD1 | c.7902G>T p.K2634N (on ENST00000520002; = p.K2633N on NM_033225.6) | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1563243199, COSV100142378; called by muse, mutect2, varscan2
- CTNND2 | c.1211G>C p.G404A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100470775; called by muse, mutect2, varscan2
- DAB1 | c.1117G>T p.A373S (on ENST00000371231; = p.A340S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.044); catalogued as rs545144491, COSV100976121; called by muse, mutect2, varscan2
- DCAF4L2 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as rs1466058320, COSV100150436; called by muse, mutect2, varscan2
- DDX18 | c.1429G>C p.G477R | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99604244; called by muse, mutect2, varscan2
- DHX33 | c.1841G>T p.R614L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV99834196; called by muse, mutect2, varscan2
- DNAAF6 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV100314394; called by muse, mutect2, varscan2
- DNAH17 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 73/101 reads (72%) | SIFT tolerated (0.74); PolyPhen benign (0.103); catalogued as COSV101101235; called by muse, mutect2, varscan2
- DOP1B | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV101214940; called by muse, mutect2, varscan2
- DPPA4 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV100169170; called by muse, mutect2, varscan2
- DSG4 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.735); catalogued as COSV100355207; called by muse, mutect2, varscan2
- DYTN | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs772233593, COSV71751873; called by muse, mutect2, varscan2
- EDNRB | c.1552C>A p.H518N (on ENST00000377211 / NM_001201397.1; = p.H428N on NM_000115.5) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100526131, COSV57526055; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 193/291 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100668325; called by muse, mutect2, varscan2
- EMC7 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV99854686; called by muse, mutect2, varscan2
- EML5 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771456651, COSV61352767; called by muse, mutect2, varscan2
- ERV3-1 | c.1029A>T p.K343N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99275117; called by muse, mutect2, varscan2
- F11 | c.1001C>A p.P334Q | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.823); catalogued as COSV99251105; called by muse, mutect2, varscan2
- F13B | c.1470T>A p.Y490* | Nonsense Mutation (SNP) | VAF 51/169 reads (30%) | catalogued as COSV100803167; called by muse, mutect2, varscan2
- FAM83B | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100173941; called by muse, mutect2, varscan2
- FAM98A | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99478985; called by muse, mutect2, varscan2
- FMN2 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV100141726; called by muse, mutect2, varscan2
- FRMPD1 | c.3841A>G p.K1281E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100899234; called by muse, mutect2
- FRYL | c.3806A>G p.Y1269C | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.885); catalogued as COSV99975442; called by muse, mutect2, varscan2
- FUT1 | c.799T>G p.W267G | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100037972; called by muse, mutect2, varscan2
- FUT9 | c.997C>A p.H333N | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as COSV100132889; called by muse, mutect2, varscan2
- GAL3ST4 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV52785136, COSV99444295; called by muse, mutect2, varscan2
- GALNT5 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as rs1029754320, COSV99374762; called by muse, mutect2, varscan2
- GC | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV56740993; called by muse, mutect2, varscan2
- GPR149 | c.982-1G>C p.X328_splice | Splice Site (SNP) | VAF 34/149 reads (23%) | catalogued as COSV101078064; called by muse, mutect2, varscan2
- GPR84 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99909913; called by muse, mutect2, varscan2
- GPRC5B | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV100314873; called by muse, mutect2, varscan2
- GRIA2 | c.1165T>G p.W389G | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99642687; called by muse, mutect2, varscan2
- GRIN2D | c.1772T>A p.V591D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99615719; called by muse, mutect2, varscan2
- HAS1 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99708182; called by muse, mutect2, varscan2
- HBS1L | c.1466G>T p.R489I | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100892500; called by muse, mutect2, varscan2
- HCLS1 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 85/326 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100100257; called by muse, varscan2
- HCN1 | c.881C>A p.A294E | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100298037; called by muse, mutect2, varscan2
- HHIPL2 | c.1888+1G>A p.X630_splice | Splice Site (SNP) | VAF 65/203 reads (32%) | catalogued as COSV100596519; called by muse, mutect2, varscan2
- HTR1A | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.034); catalogued as rs886552793, COSV100108866, COSV100108901; called by muse, mutect2, varscan2
- IGF2R | c.4414A>G p.I1472V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV100806740; called by muse, mutect2, varscan2
- IKZF3 | c.1498G>T p.A500S | Missense Mutation (SNP) | VAF 90/153 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV53101681; called by muse, mutect2, varscan2
- IMPG2 | c.2499G>T p.M833I | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV99514576; called by muse, mutect2, varscan2
- IQCG | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 268/438 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV99501938; called by muse, mutect2, varscan2
- IQCN | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV101148277; called by muse, mutect2, varscan2
- JAG2 | c.2876G>A p.C959Y | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100077810; called by muse, mutect2
- KBTBD4 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV100442807; called by muse, mutect2, varscan2
- KIAA1109 | c.14666G>T p.R4889L | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52673024, COSV99145477; called by muse, mutect2, varscan2
- KIAA1109 | c.14882G>C p.R4961T | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99145479; called by muse, mutect2, varscan2
- KIF14 | c.1662A>T p.K554N | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100950576; called by muse, mutect2, varscan2
- KIRREL2 | c.1079T>G p.L360R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV99383464; called by muse, mutect2
- KMT2A | c.10741A>T p.T3581S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV100627753; called by muse, mutect2, varscan2
- LACRT | c.317T>A p.M106K | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV99143795; called by muse, mutect2, varscan2
- LEFTY2 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV100832510; called by muse, mutect2, varscan2
- LILRA2 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780162689, COSV99252594; called by muse, mutect2, varscan2
- LMNTD1 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs773815123, COSV51446703; called by muse, mutect2, varscan2
- LRP1B | c.12002G>T p.W4001L | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1037425884, COSV101250991; called by muse, mutect2, varscan2
- LRP1B | c.9926A>G p.D3309G | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101250993; called by muse, mutect2, varscan2
- MARCHF3 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV100427664; called by muse, mutect2, varscan2
- MEGF6 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99619227; called by muse, mutect2, varscan2
- MINDY3 | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99510405; called by muse, mutect2, varscan2
- MMP9 | c.1025C>G p.S342W | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812327; called by muse, mutect2, varscan2
- MTUS2 | c.4090G>A p.V1364I (on ENST00000612955 / NM_001366650.1; = p.V343I on NM_015233.6) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV101070745; called by muse, mutect2, varscan2
- MUC16 | c.4022C>T p.P1341L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs764441333, COSV101197737; called by muse, mutect2, varscan2
- MYH14 | c.3799G>T p.G1267C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV99221531; called by muse, mutect2, varscan2
- MYO1C | c.1147A>T p.K383* (on ENST00000648651 / NM_001080779.2; = p.K348* on NM_033375.5) | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV100704164; called by muse, mutect2, varscan2
- NBPF9 | c.1448C>G p.S483* | Nonsense Mutation (SNP) | VAF 20/446 reads (4%) | catalogued as rs782734923, COSV99913166; called by muse, mutect2
- NCOA2 | c.3471C>A p.H1157Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV99144683; called by muse, mutect2, varscan2
- NGFR | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs1328910360, COSV99412635; called by muse, mutect2, varscan2
- NRSN1 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV101027189; called by muse, mutect2, varscan2
- OLFML2A | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467617032, COSV99992324; called by muse, mutect2, varscan2
- OR10J1 | c.502T>A p.F168I | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101419763; called by muse, mutect2, varscan2
- OR13C4 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99469920; called by muse, mutect2, varscan2
- OR1J2 | c.315A>G p.I105M | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV100093076; called by muse, mutect2, varscan2
- OR2C3 | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100825589; called by muse, mutect2, varscan2
- OR2L2 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV63555577; called by muse, mutect2, varscan2
- OR2M3 | c.671C>G p.A224G | Missense Mutation (SNP) | VAF 158/592 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101513392, COSV71759172; called by muse, mutect2, varscan2
- OR56B1 | c.102C>A p.H34Q | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV100402518; called by muse, mutect2, varscan2
- OR5J2 | c.194G>T p.C65F | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV100398873, COSV56622466; called by muse, mutect2, varscan2
- OR5K4 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100721286; called by muse, mutect2, varscan2
- OR6B2 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV99401077; called by muse, mutect2, varscan2
- OR6K3 | c.643G>A p.D215N (on ENST00000368146; = p.D199N on NM_001005327.2) | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as COSV100933820; called by muse, mutect2, varscan2
- OR8B4 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62069142, COSV62069882; called by muse, mutect2, varscan2
- OR8H3 | c.548del p.P183Qfs*3 | Frame Shift Del (DEL) | VAF 60/351 reads (17%) | catalogued as COSV57909204; called by pindel, varscan2
- PAQR6 | c.175A>T p.T59S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.261); catalogued as COSV52744366, COSV99430666; called by muse, mutect2, varscan2
- PCDHA12 | c.1457A>T p.K486M | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100247252, COSV56550896; called by muse, mutect2, varscan2
- PCDHGC5 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 58/183 reads (32%) | catalogued as COSV99337424; called by muse, mutect2, varscan2
- PDE4D | c.1290A>G p.E430= (on ENST00000340635 / NM_001104631.2; = p.E294= on NM_006203.4) | Splice Region (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100401308; called by muse, mutect2, varscan2
- PDZRN4 | c.1244G>A p.G415D (on ENST00000402685 / NM_001164595.2; = p.G157D on NM_013377.4) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113435; called by muse, mutect2, varscan2
- PEAR1 | c.1601C>G p.A534G | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as COSV99440459; called by muse, mutect2, varscan2
- PIGN | c.1876C>A p.L626M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV100715412; called by muse, varscan2
- PLEKHG2 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV52683662, COSV99216703; called by muse, mutect2, varscan2
- PLEKHM3 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202021467, COSV101216203; called by muse, mutect2, varscan2
- PRAG1 | c.2752G>T p.A918S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.061); catalogued as COSV100421762; called by muse, mutect2, varscan2
- PTPN22 | c.1232A>G p.K411R (on ENST00000359785 / NM_001193431.2; = p.K356R on NM_012411.5) | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV63085109; called by muse, mutect2, varscan2
- PTPRB | c.4625A>G p.K1542R | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as COSV99715470; called by muse, mutect2, varscan2
- PTPRS | c.3775G>C p.A1259P | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53626887, COSV99508801; called by muse, mutect2, varscan2
- RASAL2 | c.397A>G p.S133G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.65); catalogued as COSV62712052; called by muse, mutect2, varscan2
- ROS1 | c.2618C>A p.T873K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100876186; called by muse, mutect2, varscan2
- RPP40 | c.488A>T p.E163V | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV100123862; called by muse, mutect2, varscan2
- RYR2 | c.6301G>T p.A2101S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as rs1284018141, COSV100767337; called by muse, mutect2, varscan2
- RYR2 | c.11178C>A p.Y3726* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100767338; called by muse, mutect2, varscan2
- RYR2 | c.11179C>A p.Q3727K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100767339; called by muse, mutect2, varscan2
- SCN1A | c.1214T>C p.L405S | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100318991; called by muse, mutect2, varscan2
- SCN7A | c.1550T>A p.L517* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101313053; called by muse, mutect2, varscan2
- SCN9A | c.2075G>T p.R692I (on ENST00000303354; = p.R681I on NM_002977.3) | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as COSV100311075, COSV57608693; called by muse, mutect2, varscan2
- SECISBP2 | c.898A>G p.M300V | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as rs1275598537, COSV100368454; called by muse, mutect2, varscan2
- SEMA5B | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1308625437, COSV99530583; called by muse, mutect2, varscan2
- SGCZ | c.599C>G p.A200G | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as COSV101166444; called by muse, mutect2, varscan2
- SGSM3 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as COSV99960104, COSV99960636; called by muse, mutect2, varscan2
- SIGLEC12 | c.1247G>T p.G416V (on ENST00000291707 / NM_053003.4; = p.G298V on NM_033329.2) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52459243, COSV52465931; called by muse, mutect2, varscan2
- SLC13A3 | c.212C>G p.P71R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51720739, COSV99286026; called by muse, mutect2, varscan2
- SLC39A13 | c.649A>G p.S217G | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100712619; called by muse, mutect2, varscan2
- SLC9C1 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99997172; called by muse, mutect2, varscan2
- SNX14 | c.625A>G p.R209G (on ENST00000314673 / NM_001350535.1; = p.R165G on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV100121387; called by muse, mutect2, varscan2
- ST7 | c.1342C>T p.Q448* (on ENST00000446490; = p.L525= on NM_018412.4) | Nonsense Mutation (SNP) | VAF 117/410 reads (29%) | catalogued as COSV100127443; called by muse, mutect2, varscan2
- SVEP1 | c.5312C>A p.S1771* | Nonsense Mutation (SNP) | VAF 69/118 reads (58%) | catalogued as COSV99928120; called by muse, mutect2, varscan2
- SYCP1 | c.1675T>A p.L559M | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as COSV101050712; called by muse, mutect2, varscan2
- TACC1 | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99392759; called by muse, mutect2, varscan2
- TAF2 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs762057882, COSV100978356; called by muse, mutect2, varscan2
- TBC1D4 | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100884497; called by muse, mutect2, varscan2
- TBL1XR1 | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100763504; called by muse, mutect2, varscan2
- TEX14 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53619667, COSV99543623; called by muse, mutect2, varscan2
- THSD7B | c.2423G>T p.C808F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99743036, COSV99747229; called by muse, mutect2, varscan2
- THSD7B | c.2424C>A p.C808* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99743041; called by muse, mutect2, varscan2
- TLK1 | c.407-2A>G p.X136_splice | Splice Site (SNP) | VAF 44/155 reads (28%) | catalogued as COSV100687220; called by muse, mutect2, varscan2
- TLL1 | c.2099T>G p.V700G | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99285826; called by muse, mutect2, varscan2
- TNFRSF11A | c.525T>A p.C175* | Nonsense Mutation (SNP) | VAF 39/116 reads (34%) | catalogued as COSV99499878; called by muse, mutect2, varscan2
- TRPC4 | c.1768C>G p.H590D | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100155631; called by muse, mutect2, varscan2
- TRPV2 | c.1324G>T p.G442W | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100641106; called by muse, mutect2, varscan2
- TSPYL2 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.089); catalogued as COSV100966256; called by muse, mutect2, varscan2
- TTN | c.51500C>T p.P17167L (on ENST00000591111; = p.P9743L on NM_003319.4) | Missense Mutation (SNP) | VAF 44/90 reads (49%) | PolyPhen probably damaging (0.999); catalogued as COSV100591369; called by muse, mutect2, varscan2
- TTN | c.23577A>T p.R7859S (on ENST00000591111; = p.R6932S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/95 reads (47%) | PolyPhen benign (0.121); catalogued as rs1162009739, COSV100591371; called by muse, mutect2, varscan2
- TTN | c.13147C>G p.P4383A (on ENST00000591111; = p.P4337A on NM_003319.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | PolyPhen probably damaging (0.997); catalogued as COSV100591373; called by muse, mutect2, varscan2
- TTN | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 51/202 reads (25%) | PolyPhen possibly damaging (0.887); catalogued as COSV100591382, COSV100601515; called by muse, mutect2, varscan2
- TXLNB | c.1257G>T p.M419I | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759525871, COSV100624795, COSV100624859; called by muse, mutect2, varscan2
- UAP1 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99617332; called by muse, mutect2, varscan2
- UAP1 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99617337; called by muse, mutect2, varscan2
- UGT2B7 | c.1031C>G p.P344R | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100535081, COSV59445338; called by muse, mutect2, varscan2
- UMOD | c.1831G>C p.A611P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as COSV100207937; called by muse, mutect2, varscan2
- URB2 | c.2371A>G p.I791V | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1003949639, COSV99270552; called by muse, mutect2, varscan2
- USH1G | c.944T>C p.M315T | Missense Mutation (SNP) | VAF 91/159 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1480501046, COSV100140284; called by muse, mutect2, varscan2
- VCAN | c.1454A>T p.E485V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99424390; called by muse, mutect2, varscan2
- VPS16 | c.1612-2A>T p.X538_splice | Splice Site (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100988238; called by muse, mutect2, varscan2
- WBP11 | c.1123A>G p.K375E | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV99660515; called by muse, mutect2, varscan2
- WIF1 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 34/115 reads (30%) | catalogued as COSV99682510; called by muse, mutect2, varscan2
- WSCD1 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as rs770718752, COSV100496330; called by muse, mutect2, varscan2
- YES1 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV100099124; called by muse, mutect2, varscan2
- ZC4H2 | c.450del p.I151Sfs*36 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as COSV62004363; called by mutect2, pindel, varscan2
- ZIM3 | c.1318A>G p.T440A | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV99517559, COSV99518191, COSV99518981; called by muse, mutect2, varscan2
- ZMIZ2 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99536440; called by muse, mutect2, varscan2
- ZNF114 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100251885; called by muse, mutect2, varscan2
- ZNF189 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99407068; called by muse, mutect2, varscan2
- ZNF208 | c.2999C>A p.P1000H | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101236700, COSV68111104; called by muse, mutect2, varscan2
- ZNF396 | c.166A>T p.R56W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100108426; called by muse, mutect2, varscan2
- ZNF462 | c.4709T>C p.F1570S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.468); catalogued as COSV99470601; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100605902; called by muse, mutect2, varscan2
- ZNF572 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs769832727, COSV100073736; called by muse, mutect2, varscan2
- ZNF614 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571613; called by muse, mutect2, varscan2
- ZSCAN20 | c.1784C>A p.A595D | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100792470, COSV63681700; called by muse, mutect2, varscan2
- DCANP1 | c.253del p.A85Qfs*89 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- FCGBP | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- IBA57 | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- IGHV3-30 | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 76/673 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IGHV3-38 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- IGKV3-15 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2
- IGKV6D-41 | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOS1 | c.1577del p.P526Rfs*39 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- OPN1MW | c.403del p.L135Cfs*28 | Frame Shift Del (DEL) | VAF 27/58 reads (47%) | called by mutect2, pindel, varscan2
- OR6Y1 | c.341del p.C114Sfs*16 | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | called by mutect2, pindel, varscan2
- PDE10A | c.1744del p.L582Wfs*33 | Frame Shift Del (DEL) | VAF 38/156 reads (24%) | called by mutect2, pindel, varscan2
- PKD1L1 | c.6797_6802dup p.L2267_R2268insKL | In Frame Ins (INS) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- PPM1K | c.474_482del p.L160_L162del | In Frame Del (DEL) | VAF 18/96 reads (19%) | called by mutect2, pindel, varscan2
- TRDV1 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TRIM51 | c.740del p.A247Vfs*20 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, varscan2
- TRIM51 | c.744del p.F248Lfs*19 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | called by mutect2*, pindel, varscan2*
- ACCSL | c.618T>C p.D206= | Silent (SNP) | VAF 85/257 reads (33%) | catalogued as COSV101122141; called by muse, mutect2, varscan2
- AGXT2 | c.100C>A p.R34= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as COSV99183692; called by muse, mutect2, varscan2
- ANKRD36B | c.1638G>A p.P546= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1219149135; called by muse, mutect2, varscan2
- AP5M1 | c.1287T>C p.Y429= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV99840944; called by muse, mutect2, varscan2
- BAZ2B | c.2925G>T p.A975= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV54275211, COSV54277257; called by muse, mutect2, varscan2
- BCAS3 | c.1413G>A p.L471= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as rs1452880559, COSV101174935; called by muse, mutect2, varscan2
- CACNA1E | c.558G>T p.L186= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100701229; called by muse, mutect2, varscan2
- CDH12 | c.1848G>A p.A616= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs139945013; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLIC5 | c.1098C>T p.I366= (on ENST00000185206 / NM_001370649.1; = p.I207= on NM_016929.5) | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs376835561; called by muse, mutect2, varscan2
- CNDP2 | c.21G>A p.L7= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1177001121, COSV100158874; called by muse, mutect2, varscan2
- CRISPLD1 | c.543T>C p.C181= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV100081480; called by muse, mutect2, varscan2
- FLT4 | c.162G>A p.Q54= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99985734; called by muse, mutect2, varscan2
- GRIA4 | c.2209C>A p.R737= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV99228292; called by muse, mutect2, varscan2
- IGKV2-30 | c.312G>A p.E104= | Silent (SNP) | VAF 62/236 reads (26%) | catalogued as rs1383904059; called by muse, mutect2, varscan2
- IRX4 | c.519C>T p.G173= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs61748182; called by muse, varscan2
- KALRN | c.8941C>A p.R2981= (on ENST00000360013 / NM_001024660.4; = p.R1284= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV52264112, COSV99360857; called by muse, mutect2, varscan2
- KDSR | c.66C>T p.L22= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1188285465, COSV100430135; called by muse, mutect2, varscan2
- LGSN | c.366T>C p.G122= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as COSV101040189; called by muse, mutect2, varscan2
- LORICRIN | c.885C>T p.V295= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100907266; called by muse, mutect2
- LRP1B | c.12327C>G p.V4109= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs768100103, COSV101250990, COSV67252267; called by muse, mutect2, varscan2
- LRRK2 | c.3456T>C p.C1152= | Silent (SNP) | VAF 68/256 reads (27%) | catalogued as COSV100108867, COSV54154569; called by muse, mutect2, varscan2
- LUZP2 | c.306A>T p.S102= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV100418693; called by muse, mutect2, varscan2
- MIA3 | c.2584C>T p.L862= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs748561305, COSV100719233; called by muse, mutect2, varscan2
- MMP9 | c.501C>T p.V167= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100812326; called by muse, mutect2, varscan2
- NAALAD2 | c.171T>A p.A57= | Silent (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2
- NCKAP1L | c.423C>A p.V141= | Silent (SNP) | VAF 103/330 reads (31%) | catalogued as COSV99514328; called by muse, mutect2, varscan2
- NLRP2 | c.1342C>A p.R448= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99671798; called by muse, mutect2, varscan2
- NOTCH2 | c.60G>A p.A20= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99862446; called by muse, mutect2, varscan2
- OR2Y1 | c.777C>G p.L259= | Silent (SNP) | VAF 75/263 reads (29%) | catalogued as COSV100322655; called by muse, mutect2, varscan2
- OR4D10 | c.501T>C p.P167= | Silent (SNP) | VAF 61/207 reads (29%) | catalogued as COSV101596990; called by muse, mutect2, varscan2
- OR5W2 | c.30T>C p.T10= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs139902439, COSV100747524; called by muse, mutect2, varscan2
- PCDHGA12 | c.1911G>T p.A637= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as rs749221752, COSV99337419; called by muse, mutect2, varscan2
- PCSK1 | c.978C>A p.I326= | Silent (SNP) | VAF 91/244 reads (37%) | catalogued as COSV100226769; called by muse, mutect2, varscan2
- POPDC2 | c.978C>A p.A326= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99950795; called by muse, mutect2, varscan2
- POU4F3 | c.738G>T p.P246= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs368459497, COSV100046778, COSV57942770; called by muse, mutect2, varscan2
- RUVBL2 | c.273G>C p.A91= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV55486711, COSV99668761; called by muse, mutect2, varscan2
- SCAF1 | c.3267C>T p.P1089= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100862028; called by muse, mutect2, varscan2
- SEMA3G | c.2193C>T p.C731= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as COSV99201854; called by muse, mutect2, varscan2
- SEZ6L | c.450G>T p.A150= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99961166; called by muse, mutect2, varscan2
- SIPA1L3 | c.3117G>A p.P1039= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs139844747; called by muse, mutect2, varscan2
- SNTB2 | c.1374G>A p.R458= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as COSV100292959; called by muse, mutect2, varscan2
- TCAF1 | c.87G>C p.L29= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100584535; called by muse, mutect2, varscan2
- TLN1 | c.1755G>T p.T585= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100147217; called by muse, mutect2, varscan2
- TNIK | c.2817A>G p.P939= | Silent (SNP) | VAF 159/261 reads (61%) | catalogued as COSV52675567; called by muse, mutect2, varscan2
- TXNIP | c.864C>T p.V288= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV100997242; called by muse, mutect2, varscan2
- URGCP | c.2484C>T p.P828= (on ENST00000453200 / NM_001077663.3; = p.P819= on NM_017920.4) | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs372395023; called by muse, mutect2, varscan2
- VN1R2 | c.1092T>A p.P364= | Silent (SNP) | VAF 85/264 reads (32%) | catalogued as COSV100447753, COSV59038880; called by muse, mutect2, varscan2
- ZFYVE16 | c.3837C>T p.S1279= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV100566153; called by muse, mutect2, varscan2
- ZNF335 | c.2112C>T p.S704= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV59820154; called by muse, mutect2, varscan2
- DTNA | c.1094+1385G>A | Intron (SNP) | VAF 31/111 reads (28%) | catalogued as COSV52011345, COSV99310507; called by muse, mutect2, varscan2
- GTF2A1 | c.338-1075G>T | Intron (SNP) | VAF 38/186 reads (20%) | catalogued as COSV99993282; called by muse, mutect2, varscan2
- GTF2A1 | c.338-1076G>A | Intron (SNP) | VAF 38/183 reads (21%) | catalogued as COSV99993283; called by muse, mutect2, varscan2
- MIR124-2 | n.17C>A | RNA (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- SNORD115-21 | n.37G>T | RNA (SNP) | VAF 124/343 reads (36%) | called by muse, mutect2, varscan2
- SSPOP | n.7536C>T | RNA (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100022064; called by muse, mutect2, varscan2
- TCP10L3 | n.2559C>T | RNA (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100832908, COSV64750036; called by muse, varscan2
- TTN | c.10360+5377C>A | Intron (SNP) | VAF 46/102 reads (45%) | catalogued as COSV100591379; called by muse, mutect2, varscan2
